Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4843, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4843-01A (Primary Tumor).

FINAL DIAGNOSIS

RIGHT KIDNEY, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 3 OF 4, 6.8 cm IN GREATEST DIMENSION.
- B. APPROXIMATELY 5% OF THE TUMOR IS NECROTIC.
- C. THE TUMOR INVOLVES THE ADIPOSE TISSUE OF THE RENAL SINUS.
- D. NO DEFINITE ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. VASCULAR AND URETERAL RESECTION MARGINS ARE NEGATIVE FOR TUMOR.
- F. INVASION OF PERINEPHRIC ADIPOSE TISSUE BY TUMOR IS NOT IDENTIFIED (see comment).
- G. NO EVIDENCE OF NEOPLASIA AT THE DEEP SURGICAL MARGIN/GEROTA'S FASCIA (see comment).
- H. PATHOLOGIC TNM STAGING: pT3a Nx Mx.

Source: NCI Genomic Data Commons file f0fbf85c-351b-431b-ba45-60ad2ba6305a (TCGA-B0-4843.07830949-8CDA-428E-9ADB-53372831ED9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).